Somatic mutation profile of tumor specimen TARGET-30-PATXKG-01A (aliquot TARGET-30-PATXKG-01A-01D) from TARGET case TARGET-30-PATXKG, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.9 years (704 days).
Specimen TARGET-30-PATXKG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58512889-d373-4426-b7ef-51f1e6e2c70c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATXKG-10A (Blood Derived Normal), aliquot TARGET-30-PATXKG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8316c6b2-a1c6-43f7-a71e-3be597dffc3c

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A3 | c.9255G>T p.Q3085H | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as COSV55110362; called by muse, mutect2, varscan2
- USP6 | c.4043G>T p.C1348F | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); catalogued as COSV51482930, COSV51497408; called by muse, mutect2, varscan2
- AHNAK2 | c.12447C>A p.G4149= | Silent (SNP) | VAF 24/356 reads (7%) | catalogued as rs780638014; called by muse, mutect2
- PTK6 | c.*81C>T | 3'UTR (SNP) | VAF 35/184 reads (19%) | catalogued as rs564522525, COSV99420456; called by muse, mutect2, varscan2
